Gene-level copy-number profile of tumor specimen TCGA-QR-A700-01A from TCGA case TCGA-QR-A700, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 67.7 years (24,734 days).
Specimen TCGA-QR-A700-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PCPG.f91c39e3-34de-4a7b-94a7-c85dd701f233.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QR-A700-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cb05f157-f9a2-4413-9ac4-273713304c06

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 171; copy number 2: 20,846; copy number 3: 12,220; copy number 4: 14,175; copy number 5: 9,410; copy number 6: 2,962; copy number 7: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QR-A700-01A-11D-A35C-01): tumor purity 0.74, ploidy 3.01, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12,405 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:234,629,311–234,760,056, 8 genes, copy number 5: LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672.
- chr2:38,814–23,199,056, 337 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:23,385,179–23,708,611, 1 gene, copy number 5 (within-gene range 4–5): KLHL29.
- chr2:23,616,499–52,702,615, 516 genes, copy number 5–6 (broad region; genes not listed).
- chr2:53,470,447–145,588,024, 1,732 genes, copy number 5 (broad region; genes not listed).
- chr2:145,600,907–145,603,423, 1 gene, copy number 5: AC079163.1.
- chr2:147,713,455–182,131,398, 499 genes, copy number 5 (broad region; genes not listed).
- chr2:182,909,115–198,772,356, 184 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:199,760,544–242,160,153, 887 genes, copy number 5 (broad region; genes not listed).
- chr7:70,972–57,837,046, 1,078 genes, copy number 6–7 (broad region; genes not listed).
- chr7:63,011,463–159,233,377, 1,935 genes, copy number 5–6 (within-gene range 1–6) (broad region; genes not listed).
- chr12:13,371,089–13,982,002, 2 genes, copy number 5 (within-gene range 4–5): LINC01559, GRIN2B.
- chr12:13,526,854–32,993,754, 341 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:72,087,266–79,989,218, 98 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:111,339,527–112,898,881, 41 genes, copy number 5 (within-gene range 4–5): RNA5SP373, PHETA1, LINC02356, HSPA8P14, SH2B3, ATXN2, U7, IFITM3P5, ATXN2-AS, BRAP, PCNPP1, ACAD10, AC002996.1, ALDH2, MIR6761, MAPKAPK5-AS1, MAPKAPK5, RPS2P41, ADAM1A, ADAM1B, TMEM116, SLC25A3P2, AC004024.1, ERP29, AC073575.2, NAA25, MIR3657, AC073575.1, Y_RNA, TRAFD1, Y_RNA, HECTD4, MIR6861, AC004217.1, RN7SKP71, RPL7AP60, AC004217.2, RPL6, PTPN11, RPH3A, MIR1302-1.
- chr15:19,878,555–43,266,928, 743 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr15:45,235,930–71,783,383, 573 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr15:73,255,334–101,933,350, 772 genes, copy number 5 (broad region; genes not listed).
- chr18:47,390–34,891,844, 592 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr18:35,241,030–49,599,185, 189 genes, copy number 5 (broad region; genes not listed).
- chr18:49,822,789–50,195,147, 1 gene, copy number 5 (within-gene range 4–5): MYO5B.
- chr18:49,969,721–79,816,529, 429 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–13,169,103, 271 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:13,995,369–16,053,197, 1 gene, copy number 5 (within-gene range 4–5): MACROD2.
- chr20:14,223,041–64,313,132, 1,174 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 171. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
